Surgical pathology report (de-identified scan), TCGA case TCGA-BI-A0VS, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-BI-A0VS-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

PART 1: LYMPH NODE, RIGHT EXTERNAL ILIAC, EXCISION –
ONE (1) BENIGN LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 2: UTERUS, CERVIX, UPPER VAGINAL, BILATERAL ADNEXA, RADICAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY (434 GRAMS) –

- A. INVASIVE SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED.
- B. TUMOR MEASURES 2 X 1 CM (gross measurement).
- C. TUMOR THICKNESS IS 7MM AND DEPTH OF INVASION IS 7mm (slide 2E) (SEE COMMENT)
- D. NO DEFINITIVE LYMPHOVASCULAR INVASION IS IDENTIFIED.
- E. CERVICAL INTRAEPITHELIAL NEOPLASIA 3 (CIN 3).
- F. ENDOCERVIX: WITH FOCAL EXTENSION OF TUMOR INTO ENDOCERVIX, SQUAMOUS METAPLASIA, TUNNELCLUSTERS AND CERVICAL ENDOMETRIOSIS.
- G. UPPER VAGINA: NO TUMOR SEEN.
- H. LOWER UTERINE SEGMENT: NO TUMOR SEEN.
- I. ENDOMETRIUM: DISORDERED PROLIFERATIVE PATTERN, NO TUMOR SEEN.
- J. LEIOMYOMA, MEASURING 9.0 CM.
- K. RIGHT AND LEFT OVARIES WITH PHYSIOLOGICAL CHANGES, NO TUMOR SEEN.
- L. RIGHT AND LEFT FALLOPIAN TUBES WITH NO TUMOR SEEN.
- M. RIGHT AND LEFT PARAMETRIA WITH NO TUMOR SEEN.

PART 3: LYMPH NODE, RIGHT OBTURATOR, EXCISION –
ONE (1) REACTIVE LYMPH NODE, NO TUMOR SEEN (0/1).

PART 4: LYMPH NODE, LEFT EXTERNAL ILIAC, EXCISION –
ONE (1) BENIGN LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 5: LYMPH NODE, LEFT OBTURATOR, EXCISION –
THREE (3) BENIGN LYMPH NODES WITH FATTY REPLACEMENT, NO TUMOR SEEN (0/3).

PART 6: LYMPH NODE, LEFT COMMON ILIAC, EXCISION –
ONE (1) BENIGN LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 7: LYMPH NODE, LEFT PERIAORTIC, EXCISION –
A. NO LYMPH NODE IDENTIFIED.
B. FIBROFATTY TISSUE, NO TUMOR SEEN (0/0).

PART 8: LYMPH NODE, RIGHT COMMON ILIAC, EXCISION –
A. NO LYMPH NODE IDENTIFIED.
B. FIBROFATTY TISSUE, NO TUMOR SEEN (0/0).

PART 9: LYMPH NODE, RIGHT PERIAORTIC, EXCISION –
ONE (1) BENIGN LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

ICD-0-3

carcinoma, squamous cell 8070/3
Site: cervix, NOS C53.9

lw
11/27/11

COMMENT:

#1: The depth of invasion is measured as the "epithelial-stromal junction of the adjacent dermal papillae to the deepest point of invasion" is equal to 7mm. The thickness of the tumor is measured as "from the surface of the tumor to the deepest point of invasion" is also measured to be 7mm.

[page 2 of 2]
PATIENT HISTORY:

No entry. LMP: Not applicable.

PRE-OP DIAGNOSIS: Cervical cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical hysterectomy, insertion of suprapubic PPALND.

CASE SYNOPSIS:**SYNOPTIC - PRIMARY UTERINE CERVIX TUMORS: HYSTERECTOMY AND CONIZATION****TUMOR TYPE:**

Squamous cell carcinoma

HISTOLOGIC GRADE:

Poorly differentiated

TUMOR SIZE:

High grade squamous intraepithelial lesion (HSIL)

TUMOR LOCATION:

Maximum dimension: 2.0 cm

DEPTH OF INVASION:

Ectocervix

TUMOR THICKNESS:

1/3 of cervical thickness

HORIZONTAL SPREAD:

Tumor thickness: 7 mm

EXTENSION OF TUMOR (Invasive neoplasias only): Extension of Tumor: 2.0x1.0**KOILOCYTES:**

Absent

INTRAGLANDULAR INVOLVEMENT BY SIL: Absent**NON-NEOPLASTIC UTERUS:**

Leiomyoma

MARGINS OF RESECTION:

Vaginal margin is negative for tumor

Parametrium margin is negative for tumor

Mitotic rate: 0 / 10 HPF

MITOTIC RATE:

No angiolymphatic invasion

ANGIOLYMPHATIC INVASION:

Number of lymph nodes positive: 0

LYMPH NODES POSITIVE:

Total number of lymph nodes examined: 7

LYMPH NODES EXAMINED:**LYMPH NODE GROUPS INVOLVED:** Obturator lymph nodes, Right, Obturator lymph nodes, Left, Common iliac lymph nodes, Left, Internal iliac lymph nodes, Right, External iliac lymph nodes, Right, External iliac lymph nodes, Left**EXTRANODAL EXTENSION:**

No

T STAGE, PATHOLOGIC:

pT1b

N STAGE, PATHOLOGIC:

pN0

M STAGE, PATHOLOGIC:

pMX

FIGO STAGE:

IB

RESIDUAL TUMOR:

Rx

Dual/Syncraneous Primary: Noted		

hwt

Source: NCI Genomic Data Commons file 1f48c1bf-bfcc-4a68-b91e-4bcd2470d11f (TCGA-BI-A0VS.5E58A8B7-0F96-4604-9BDE-66A8C2DF7B58.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).